Somatic mutation profile of tumor specimen 0DJKL4 from CCDI case PBBWXT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 17.4 years (6,343 days).
Specimen 0DJKL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce2e3a7c-e940-462e-8131-62c0a6c5ab9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJKK9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e89a6f6-5517-4980-887c-654c22a94ad7

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2279C>A p.T760N (on ENST00000651564; = p.T713N on NM_015692.5) | Missense Mutation (SNP) | VAF 162/423 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52231183; called by muse, mutect2, varscan2
- SCARF2 | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1375410421; called by muse, mutect2
- TG | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 22/828 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs1031907068; called by muse, mutect2
- WNT2B | c.469G>A p.A157T (on ENST00000369684 / NM_024494.3; = p.A138T on NM_004185.4) | Missense Mutation (SNP) | VAF 229/648 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1258923351, COSV56672795; called by muse, mutect2, varscan2
- GRID2 | c.1934T>C p.I645T | Missense Mutation (SNP) | VAF 238/616 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MAP3K15 | c.3401-1G>A p.X1134_splice | Splice Site (SNP) | VAF 163/455 reads (36%) | called by muse, mutect2, varscan2
- SRP68 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 158/395 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ZNF160 | c.1243C>T p.H415Y | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANK3 | c.12596-201G>T | Intron (SNP) | VAF 119/282 reads (42%) | called by muse, mutect2, varscan2
- SMIM13 | chr6:11137409 G>A | 3'Flank (SNP) | VAF 136/402 reads (34%) | called by muse, mutect2, varscan2
